Somatic mutation profile of tumor specimen C3N-01825-01 (aliquot CPT0097710009) from CPTAC case C3N-01825, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 70.3 years (25,659 days).
Specimen C3N-01825-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0bf45c8-1999-406d-a309-5c0fd6080737.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01825-31 (Blood Derived Normal), aliquot CPT0097750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6722124-fc6b-4cc2-adfd-3e04a1c9eb7b

The open-access MAF lists 43 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 7, Frame Shift Del 1, Nonsense Mutation 1, 3'UTR 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 54/482 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANTXRL | c.1516G>T p.A506S | Missense Mutation (SNP) | VAF 45/890 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.362); catalogued as rs1554967155; called by muse, mutect2
- ARHGEF3 | c.86A>G p.K29R | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs888496331; called by muse, mutect2, varscan2
- CDCA7L | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301630062, COSV60966655, COSV60982391; called by muse, mutect2
- CNTN1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 15/501 reads (3%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.957); catalogued as COSV61639221; called by muse, mutect2
- EIF4E2 | c.463A>G p.M155V | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs772833654; called by muse, mutect2
- ERBB3 | c.3019C>T p.P1007S | Missense Mutation (SNP) | VAF 73/774 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs750884386; called by muse, mutect2
- ESRP1 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); catalogued as rs775408778, COSV64408509; called by muse, mutect2
- FBXW7 | c.1508C>T p.A503V (on ENST00000281708 / NM_001349798.2; = p.A423V on NM_018315.5) | Missense Mutation (SNP) | VAF 63/459 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV55899659; called by muse, mutect2, varscan2
- GAS2L3 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 18/263 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs767269799, COSV57158008; called by muse, mutect2
- HCN1 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 16/150 reads (11%) | catalogued as COSV100301088; called by muse, varscan2
- HPS5 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 21/411 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765064234; called by muse, mutect2
- KLC4 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs768070146, COSV52438529; called by muse, mutect2, varscan2
- NFKBIZ | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 23/388 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); catalogued as rs1000263983; called by muse, mutect2
- PWWP2B | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 47/396 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.026); catalogued as rs780435205; called by muse, mutect2, varscan2
- SERPINB12 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.966); catalogued as rs367650461; called by muse, mutect2, varscan2
- STUB1 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs1235455048; called by muse, mutect2, varscan2
- STUM | c.339G>T p.W113C | Missense Mutation (SNP) | VAF 38/378 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64684807; called by muse, mutect2, varscan2
- TBL3 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1172110224, COSV100225089; called by muse, mutect2
- TRABD2A | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs763234862; called by muse, mutect2
- WDFY4 | c.3698G>T p.R1233L | Missense Mutation (SNP) | VAF 38/544 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100301932; called by muse, mutect2
- ABCC11 | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- ABTB2 | c.1598G>A p.G533E | Missense Mutation (SNP) | VAF 46/512 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADA | c.616A>G p.K206E | Missense Mutation (SNP) | VAF 74/610 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DENND2B | c.2266G>A p.V756M | Missense Mutation (SNP) | VAF 17/356 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- FCHO1 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2
- KCNK3 | c.180G>T p.E60D | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2
- ME1 | c.129G>T p.L43F | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLA2R1 | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- SOX11 | c.195del p.K66Rfs*25 | Frame Shift Del (DEL) | VAF 42/337 reads (12%) | called by mutect2, pindel, varscan2
- TET1 | c.4996G>C p.D1666H | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TGFB3 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 67/624 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- TRPS1 | c.1664A>T p.N555I (on ENST00000220888 / NM_001330599.2; = p.N568I on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/500 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); called by muse, mutect2
- BCL2L12 | c.469C>T p.L157= | Silent (SNP) | VAF 9/228 reads (4%) | catalogued as COSV55863871; called by muse, mutect2
- FOXJ1 | c.1188G>A p.P396= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as rs550111178, COSV100538142; called by muse, mutect2, varscan2
- G6PD | c.186C>T p.P62= | Silent (SNP) | VAF 32/378 reads (8%) | catalogued as rs781875587; called by muse, mutect2
- PKD2 | c.720C>T p.G240= | Silent (SNP) | VAF 57/512 reads (11%) | called by muse, mutect2, varscan2
- SLC10A2 | c.708G>A p.A236= | Silent (SNP) | VAF 46/453 reads (10%) | catalogued as rs1041398293, COSV55360173; called by muse, varscan2
- TBC1D25 | c.576C>T p.V192= | Silent (SNP) | VAF 20/390 reads (5%) | catalogued as COSV100952112; called by muse, mutect2
- UTRN | c.8854A>C p.R2952= | Silent (SNP) | VAF 10/238 reads (4%) | called by muse, mutect2
- ATP5F1E | c.-28G>T | 5'UTR (SNP) | VAF 15/446 reads (3%) | called by muse, mutect2
- ITPK1 | c.*3009G>C | 3'UTR (SNP) | VAF 29/253 reads (11%) | called by muse, mutect2, varscan2
- SLC25A14 | c.594+372C>T | Intron (SNP) | VAF 17/284 reads (6%) | called by muse, mutect2
